Somatic mutation profile of tumor specimen TCGA-4A-A93W-01A (aliquot TCGA-4A-A93W-01A-11D-A36X-10) from TCGA case TCGA-4A-A93W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.0 years (24,117 days).
Specimen TCGA-4A-A93W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 544b2030-5a9e-4159-b579-fbdf4b650a46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4A-A93W-10A (Blood Derived Normal), aliquot TCGA-4A-A93W-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c57f7d67-351b-4b0b-9247-79b854cbc8bf

The open-access MAF lists 108 somatic variants for this specimen: 84 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Frame Shift Del 12, Nonsense Mutation 5, Splice Region 1, Splice Site 1, Frame Shift Ins 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 89/145 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs786202724, CM1210646, CM990852, COSV59257346; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.3979G>C p.A1327P | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101316115; called by muse, mutect2, varscan2
- ANKRD11 | c.3971C>T p.S1324F | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV99969733, COSV99970167; called by muse, mutect2, varscan2
- ANXA7 | c.416A>C p.Q139P | Missense Mutation (SNP) | VAF 136/333 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100873461; called by muse, mutect2, varscan2
- ARHGAP9 | c.702T>G p.N234K | Missense Mutation (SNP) | VAF 81/192 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV100712475; called by muse, mutect2, varscan2
- ARRDC5 | c.467G>T p.G156V (on ENST00000381781; = p.G142V on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101108188, COSV67788005; called by muse, mutect2, varscan2
- ASB16 | c.370A>C p.T124P | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV99518942; called by muse, mutect2, varscan2
- ASPG | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV101496413; called by muse, mutect2
- ATCAY | c.197del p.P66Qfs*92 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | catalogued as COSV56658355, COSV99040873; called by mutect2, pindel, varscan2
- ATP8B3 | c.980A>T p.Y327F | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as COSV100034527; called by muse, mutect2, varscan2
- BMP1 | c.2891T>G p.I964S | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100115052; called by muse, mutect2, varscan2
- C22orf42 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.728); catalogued as COSV101173337; called by muse, mutect2, varscan2
- CXCR6 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99945830; called by muse, mutect2
- DAGLA | c.1729C>A p.L577M | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99944474; called by muse, mutect2, varscan2
- DECR1 | c.737A>C p.K246T | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV55170303; called by muse, mutect2, varscan2
- DGKD | c.491A>T p.H164L (on ENST00000264057 / NM_152879.3; = p.H120L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99896601; called by muse, mutect2, varscan2
- DGKH | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99819011; called by muse, mutect2, varscan2
- DGKK | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV101053068; called by muse, mutect2, varscan2
- EGLN2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV100393785; called by muse, mutect2, varscan2
- ELP4 | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs745713244, COSV99541090; called by muse, mutect2, varscan2
- FAM20C | c.820A>G p.M274V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs777225574, COSV100570460; called by muse, mutect2, varscan2
- FBXO17 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as COSV99494173; called by muse, mutect2, varscan2
- FGFR4 | c.709T>C p.Y237H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99450128; called by muse, mutect2
- GRHL1 | c.1081T>C p.F361L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257920; called by muse, mutect2
- HEATR4 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.219); catalogued as COSV100620449; called by muse, mutect2, varscan2
- HOXC6 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99679097; called by muse, mutect2, varscan2
- IARS2 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs770464072, COSV56964296; called by muse, mutect2, varscan2
- IGSF9B | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482345173, COSV100317872; called by muse, mutect2, varscan2
- INO80D | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.35); catalogued as rs1402672090, COSV101305852; called by muse, mutect2, varscan2
- JPH3 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99413548; called by muse, mutect2, varscan2
- KLHL23 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 121/266 reads (45%) | catalogued as COSV99775892; called by muse, mutect2, varscan2
- KMT2C | c.5685G>A p.M1895I | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100072975; called by muse, mutect2, varscan2
- KRT17 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV100245173; called by muse, mutect2, varscan2
- LBHD1 | c.659C>T p.S220L (on ENST00000431002 / NM_001367940.1; = p.S194L on NM_024099.3) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.073); catalogued as rs1431823561, COSV100649161; called by muse, mutect2, varscan2
- LHX4 | c.351C>A p.C117* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as COSV99761655; called by muse, mutect2, varscan2
- LYN | c.1527G>C p.Q509H | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV101571239, COSV72923585; called by muse, mutect2
- LYN | c.1529A>T p.Q510L | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101571240; called by muse, mutect2
- MAGEE1 | c.2768G>A p.R923K | Missense Mutation (SNP) | VAF 125/350 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV63912191; called by muse, mutect2, varscan2
- MEF2C | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as rs1175233907, COSV100425532; called by muse, mutect2
- MERTK | c.2079+1G>C p.X693_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99774804; called by muse, mutect2, varscan2
- MFAP3L | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759625030, COSV64371714; called by muse, mutect2, varscan2
- MYCBP2 | c.11911T>G p.S3971A (on ENST00000357337; = p.S4009A on NM_015057.5) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100630698; called by muse, mutect2, varscan2
- MYO3B | c.2751dup p.R918Tfs*41 | Frame Shift Ins (INS) | VAF 41/110 reads (37%) | catalogued as rs779012864; called by mutect2, pindel, varscan2
- NAV3 | c.4902T>G p.I1634M | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99892184; called by muse, mutect2, varscan2
- NYNRIN | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 44/100 reads (44%) | catalogued as COSV101230620; called by muse, mutect2, varscan2
- OR51A7 | c.874T>A p.C292S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100834685; called by muse, mutect2, varscan2
- PEX5L | c.178del p.L60Sfs*4 | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | catalogued as COSV55846241, COSV99828424; called by mutect2, pindel, varscan2
- PHACTR3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV63027432; called by muse, mutect2, varscan2
- PHF7 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100015471; called by muse, mutect2, varscan2
- PLEKHO2 | c.1463del p.S488Mfs*117 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV60262246; called by mutect2, varscan2
- PLOD2 | c.953T>A p.L318* | Nonsense Mutation (SNP) | VAF 178/407 reads (44%) | catalogued as COSV99282890; called by muse, mutect2, varscan2
- PPP1R13B | c.2180A>T p.Y727F | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99159669; called by muse, mutect2, varscan2
- PRKCI | c.1631C>A p.S544Y | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV55517786; called by muse, mutect2, varscan2
- PRXL2B | c.344A>T p.D115V (on ENST00000444521; = p.D85V on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1224350440, COSV99983958; called by muse, mutect2, varscan2
- PSMD13 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV100728844; called by muse, mutect2, varscan2
- PTPRT | c.2655G>C p.Q885H | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV100628168; called by muse, mutect2, varscan2
- RBM12B | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.627); catalogued as COSV101197152; called by muse, mutect2, varscan2
- S100A6 | c.141G>A p.K47= | Splice Region (SNP) | VAF 36/68 reads (53%) | catalogued as COSV100785936; called by muse, mutect2, varscan2
- SIPA1L3 | c.3158C>G p.T1053S | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99729186; called by muse, mutect2, varscan2
- SLC27A3 | c.1342G>T p.E448* (on ENST00000271857; = p.E320* on NM_024330.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as COSV99669988; called by muse, mutect2, varscan2
- SOCS6 | c.958A>T p.N320Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV101205789; called by muse, mutect2, varscan2
- SV2C | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as rs763042833, COSV100456369; called by muse, mutect2, varscan2
- TBC1D15 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100041889; called by muse, mutect2
- TCEAL3 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 116/253 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99685279; called by muse, mutect2, varscan2
- TLR5 | c.824A>T p.K275I | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100643307; called by muse, mutect2, varscan2
- TNS3 | c.686T>A p.V229D | Missense Mutation (SNP) | VAF 96/150 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100235754; called by muse, mutect2, varscan2
- TTN | c.35619A>C p.E11873D (on ENST00000591111; = p.E4449D on NM_003319.4) | Missense Mutation (SNP) | VAF 54/119 reads (45%) | PolyPhen benign (0.261); catalogued as COSV100617912; called by muse, mutect2, varscan2
- U2AF2 | c.1184A>T p.Y395F | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as COSV58274174; called by muse, mutect2, varscan2
- UBE4B | c.1320G>C p.E440D (on ENST00000343090 / NM_001105562.3; = p.E311D on NM_006048.5) | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99476921; called by mutect2, varscan2
- WDR24 | c.2685C>A p.H895Q (on ENST00000248142; = p.H765Q on NM_032259.4) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99555806; called by muse, mutect2, varscan2
- ZAN | c.1315A>G p.S439G | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100769840; called by muse, mutect2, varscan2
- ZBTB40 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100989025; called by muse, mutect2, varscan2
- ZNF543 | c.1688C>A p.T563N | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV100386820, COSV100386972; called by muse, mutect2
- ZNF594 | c.837T>A p.S279R | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.42); PolyPhen benign (0.394); catalogued as COSV101280497, COSV101280507; called by muse, mutect2, varscan2
- ZNF649 | c.90G>C p.K30N | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100725443; called by muse, mutect2, varscan2
- ABI3BP | c.1555del p.E519Kfs*2 | Frame Shift Del (DEL) | VAF 53/118 reads (45%) | called by mutect2, pindel*, varscan2
- FSD2 | c.2232del p.K744Nfs*10 | Frame Shift Del (DEL) | VAF 32/75 reads (43%) | called by mutect2, pindel, varscan2
- HNRNPA1 | c.131_132del p.V44Gfs*69 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by pindel, varscan2
- ITIH3 | c.1304del p.F435Sfs*38 | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | called by mutect2, pindel, varscan2
- MAP3K6 | c.998del p.K333Rfs*56 | Frame Shift Del (DEL) | VAF 59/168 reads (35%) | called by mutect2, pindel, varscan2
- OR4A15 | c.891_898delinsTTTG p.R297Sfs*7 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | called by pindel, varscan2*
- RNF32 | c.669del p.K223Nfs*35 | Frame Shift Del (DEL) | VAF 93/208 reads (45%) | called by mutect2, pindel, varscan2
- ZDHHC7 | c.455del p.C152Lfs*12 | Frame Shift Del (DEL) | VAF 81/220 reads (37%) | called by mutect2, pindel, varscan2
- ZKSCAN4 | c.840_841del p.H281Wfs*21 | Frame Shift Del (DEL) | VAF 32/91 reads (35%) | called by mutect2, pindel, varscan2
- C1orf43 | c.666A>C p.T222= (on ENST00000368521 / NM_001297718.2; = p.T188= on NM_015449.4) | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV100634274; called by muse, mutect2, varscan2
- C4orf46 | c.150G>A p.V50= | Silent (SNP) | VAF 96/213 reads (45%) | catalogued as COSV100309995; called by muse, mutect2, varscan2
- CHL1 | c.2814A>G p.L938= (on ENST00000397491 / NM_001253387.1; = p.L954= on NM_006614.4) | Silent (SNP) | VAF 5/117 reads (4%) | called by muse, mutect2
- CNTN6 | c.2280G>A p.R760= | Silent (SNP) | VAF 92/243 reads (38%) | catalogued as rs754634386, COSV100610965, COSV63179635; called by muse, mutect2
- CYP2S1 | c.414G>C p.L138= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100027491; called by muse, mutect2, varscan2
- ELMO3 | c.63A>G p.G21= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs1029302317, COSV100681527; called by muse, mutect2, varscan2
- GRHL1 | c.1083C>T p.F361= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV100257923; called by muse, mutect2
- HUWE1 | c.11583G>T p.G3861= | Silent (SNP) | VAF 50/103 reads (49%) | catalogued as COSV53347885; called by muse, mutect2, varscan2
- IGDCC4 | c.3501C>A p.I1167= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100732959; called by muse, mutect2
- MAPKBP1 | c.3138G>A p.E1046= (on ENST00000456763 / NM_001128608.2; = p.E1040= on NM_014994.3) | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs1329838452, COSV99529696; called by muse, mutect2, varscan2
- MTHFR | c.1140G>A p.E380= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100928232; called by muse, mutect2, varscan2
- NOL12 | c.625C>A p.R209= | Silent (SNP) | VAF 105/235 reads (45%) | catalogued as rs760440711, COSV100767151; called by muse, mutect2, varscan2
- OSBPL1A | c.1686C>A p.S562= (on ENST00000319481 / NM_080597.4; = p.S49= on NM_018030.4) | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV100112011; called by muse, mutect2, varscan2
- PAX1 | c.1560C>T p.F520= | Silent (SNP) | VAF 59/85 reads (69%) | catalogued as rs368125977, COSV101270326; called by muse, mutect2, varscan2
- PTCD1 | c.945A>G p.L315= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV99464046; called by muse, mutect2
- PTGIS | c.1113C>T p.D371= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs561620152, COSV54836179; called by muse, mutect2, varscan2
- RC3H2 | c.3471C>G p.T1157= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as COSV100605716; called by muse, mutect2, varscan2
- RYR2 | c.3126C>A p.T1042= | Silent (SNP) | VAF 77/173 reads (45%) | catalogued as COSV100771104; called by muse, mutect2, varscan2
- SASH3 | c.171A>C p.S57= | Silent (SNP) | VAF 27/346 reads (8%) | catalogued as COSV100795251; called by muse, mutect2
- SOHLH2 | c.1233G>A p.T411= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as rs758707929, COSV65901167; called by muse, mutect2, varscan2
- SULT1C4 | c.513T>C p.A171= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV99731647; called by muse, mutect2, varscan2
- TNRC6A | c.1533G>A p.E511= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV100170152; called by muse, mutect2, varscan2
- MICD | chr6:29975344 C>A | 5'Flank (SNP) | VAF 88/184 reads (48%) | called by muse, mutect2
- SMOX | c.1531-450G>C | Intron (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99603295; called by muse, mutect2, varscan2
